Gene-level copy-number profile of tumor specimen HCM-BROD-0199-C71-02A from HCMI case HCM-BROD-0199-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.1 years (17,924 days).
Specimen HCM-BROD-0199-C71-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f3ba80cb-9ed4-4f2a-91a6-b0d95e7cbb06.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0199-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/5e2a9629-530a-4f10-a2fe-3abdc46a7a1e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 8,031; copy number 2: 48,015; copy number 3: 856; copy number 4: 1,941; copy number 100: 6; copy number 103: 32.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–23,438,700, 20 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr9:23,894,990–23,956,444, 2 genes: AL365204.2, AL365204.3.
- chr10:53,802,771–55,627,942, 6 genes (within-gene range 0–1): PCDH15, RNU6-687P, AL353784.1, NEFMP1, MIR548F1, AC051618.1.
- chr10:55,599,042–55,600,728, 1 gene (within-gene range 0–1): MTRNR2L5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 38 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:51,372,736–51,665,048, 6 genes, copy number 100: AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2.
- chr7:54,933,699–55,955,239, 32 genes, copy number 103 (within-gene range 4–103): AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713.

Autosomal genes at a single copy (total copy number 1): 5,183. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
